Surgical pathology report (de-identified scan), TCGA case TCGA-D1-A0ZN, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site Mayo Clinic, specimen TCGA-D1-A0ZN-01A (Primary Tumor).

[page 1 of 2]
ICD-0-3
Adenocarcinoma, endometrioid, NOS
8380/3

Site Code: Endometrium C54.1 1/17/11 lw

DIAGNOSIS:

A. Uterus, bilateral ovaries, and fallopian tubes; hysterectomy and bilateral salpingo-oophorectomy: FIGO grade I (of III) endometrial adenocarcinoma, endometrioid type, is identified forming a mass (2.0 x 1.3 x 0.5 cm) located in the anterior uterine wall. The tumor is confined to the endometrium. The tumor does not involve the endocervix. Lymphovascular space invasion is not identified [AJCC pT1a]. Endometriosis involving the anterior uterine serosa as well as multiple (2) intramural leiomyomata (0.5 cm and 0.8 cm in greatest dimension) are also identified. The bilateral ovaries and fallopian tubes show no diagnostic abnormalities.

GROSS DESCRIPTION:

A. Received fresh labeled "uterus, right and left fallopian tubes and ovaries" is a 135.0 gram uterus with attached bilateral tubes and ovaries and an unremarkable cervix. The uterine serosa has focal fibrous adhesions. There is a 2.0 x 1.3 x 0.5 cm mass in the anterior body of the endometrial cavity with 1.9 cm myometrial thickness. There are multiple (2) intramural leiomyomas (0.5 cm and 0.8 cm in greatest dimension). There is a 2.5 x 1.8 x 1.3 cm right ovary with a smooth outer surface and a solid cut surface with a 4.8 x 0.8 cm right fallopian tube. There is a 2.5 x 2.0 x 1.1 cm left ovary with a smooth outer surface and a solid cut surface with a 4.8

[page 2 of 2]
x 0.7 cm left fallopian tube. Representative sections submitted.

BLOCK SUMMARY:

Part A: Uterus, right and left fallopian tubes and ovaries

- 1 Endometrium
- 2 Endometrium
- 3 Endometrium
- 4 Endometrium
- 5 Low uterine segment
- 6 Low uterine segment
- 7 Rt ovary
- 8 Rt fallopian tube
- 9 Lt ovary
- 10 Lt fallopian tube
- 11 Anterior uterine serosa
- 12 Anterior uterine serosa

Source: NCI Genomic Data Commons file a3c9b12e-ba94-4c3c-b661-ae893ef56fb9 (TCGA-D1-A0ZN.53DB2270-9308-47F5-BD1F-4D4C737F98AC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).